TCGA case TCGA-FL-A1YH — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Uterus, NOS; Tissue source site: University of Hawaii - Normal Study.
https://portal.gdc.cancer.gov/cases/47c49c54-95f8-42c8-94e4-411280452512

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FL-A1YH-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 310 mg.
  Slide TCGA-FL-A1YH-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100.
